Somatic mutation profile of tumor specimen TCGA-HZ-8636-01A (aliquot TCGA-HZ-8636-01A-21D-2396-08) from TCGA case TCGA-HZ-8636, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Tail of pancreas; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 58.9 years (21,501 days).
Specimen TCGA-HZ-8636-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9588303c-5b8c-4388-913a-b71f48e9810f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HZ-8636-10A (Blood Derived Normal), aliquot TCGA-HZ-8636-10A-01D-2396-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/45b9156f-25d5-49d9-9617-d2e706e75e8a

The open-access MAF lists 49 somatic variants for this specimen: 38 protein-altering or splice-affecting, 9 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 9, RNA 1, Nonsense Mutation 1, Intron 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 32/119 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.518_519insCGT p.V173dup | In Frame Ins (INS) | VAF 92/291 reads (32%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- ARMC12 | c.739C>T p.L247F (on ENST00000373866 / NM_001286574.2; = p.L274F on NM_145028.5) | Missense Mutation (SNP) | VAF 23/431 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55361310; called by muse, mutect2
- ATP12A | c.521C>T p.S174F | Missense Mutation (SNP) | VAF 15/363 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.378); catalogued as COSV99516851; called by muse, mutect2
- ATP4A | c.989G>A p.R330Q | Missense Mutation (SNP) | VAF 55/265 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.084); catalogued as COSV52872055; called by muse, mutect2, varscan2
- BANP | c.1057C>T p.P353S (on ENST00000286122; = p.P322S on NM_017869.4) | Missense Mutation (SNP) | VAF 16/248 reads (6%) | SIFT tolerated, low confidence (0.61); PolyPhen probably damaging (0.993); catalogued as COSV99620517; called by muse, mutect2
- BTF3 | c.223A>G p.K75E (on ENST00000380591 / NM_001037637.1; = p.K31E on NM_001207.4) | Missense Mutation (SNP) | VAF 32/211 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.139); catalogued as rs1332017959, COSV100246622; called by muse, mutect2, varscan2
- BTF3 | c.224A>T p.K75M (on ENST00000380591 / NM_001037637.1; = p.K31M on NM_001207.4) | Missense Mutation (SNP) | VAF 32/209 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as rs1379009626, COSV100246624; called by muse, mutect2, varscan2
- CTSK | c.573G>C p.K191N | Missense Mutation (SNP) | VAF 68/907 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV99648483; called by muse, mutect2
- DLL4 | c.661A>T p.I221F | Missense Mutation (SNP) | VAF 11/264 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.043); catalogued as COSV99989550; called by muse, mutect2
- DNASE1L1 | c.581G>A p.R194H | Missense Mutation (SNP) | VAF 161/644 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.111); catalogued as rs199865662, COSV99185801; called by muse, mutect2, varscan2
- DPYSL5 | c.755C>T p.S252L | Missense Mutation (SNP) | VAF 55/368 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.19); catalogued as rs372829541; called by muse, mutect2, varscan2
- EPB41L1 | c.1664A>G p.N555S | Missense Mutation (SNP) | VAF 37/236 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs754147491, COSV99148786; called by muse, mutect2, varscan2
- GAB3 | c.1202G>T p.G401V | Missense Mutation (SNP) | VAF 29/712 reads (4%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV100850396; called by muse, mutect2
- GNAO1 | c.428G>A p.R143Q | Missense Mutation (SNP) | VAF 87/365 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs777414554, COSV52614852; called by muse, mutect2, varscan2
- HCN4 | c.2608G>A p.G870R | Missense Mutation (SNP) | VAF 12/264 reads (5%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.921); catalogued as COSV99983182; called by muse, mutect2
- KIF3C | c.685C>T p.R229C | Missense Mutation (SNP) | VAF 24/408 reads (6%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.683); catalogued as rs1040832462, COSV99266962; called by muse, mutect2
- MAGEB1 | c.989C>T p.T330M | Missense Mutation (SNP) | VAF 86/507 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.026); catalogued as rs145293151, COSV100974796; called by muse, mutect2, varscan2
- MUC5B | c.988C>G p.P330A | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); catalogued as COSV101499977; called by muse, mutect2, varscan2
- MUC5B | c.4307C>T p.P1436L | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.522); catalogued as rs758850391, COSV71594704; called by muse, mutect2
- NEURL4 | c.2830G>A p.V944I | Missense Mutation (SNP) | VAF 22/336 reads (7%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.989); catalogued as rs1433681089, COSV100222618; called by muse, mutect2
- NUP42 | c.31C>G p.R11G | Missense Mutation (SNP) | VAF 61/242 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as rs370296256, COSV99330833; called by muse, mutect2, varscan2
- OSGEP | c.739C>T p.R247* | Nonsense Mutation (SNP) | VAF 34/626 reads (5%) | catalogued as rs551255070, COSV52833399, COSV99247839; called by muse, mutect2
- OTOP3 | c.1163C>T p.T388M | Missense Mutation (SNP) | VAF 33/333 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.397); catalogued as rs145029319; called by muse, mutect2, varscan2
- OTX2 | c.848C>T p.S283L (on ENST00000408990 / NM_172337.3; = p.S291L on NM_021728.4) | Missense Mutation (SNP) | VAF 93/477 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.283); catalogued as rs753156713, COSV59767481; called by muse, mutect2, varscan2
- PCLO | c.13036C>A p.Q4346K | Missense Mutation (SNP) | VAF 44/484 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61674427; called by muse, mutect2
- PPP1R26 | c.488C>T p.S163F | Missense Mutation (SNP) | VAF 77/338 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV100777974; called by muse, mutect2, varscan2
- RPA2 | c.86C>T p.S29L | Missense Mutation (SNP) | VAF 24/294 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.127); catalogued as rs1167754276, COSV100536024; called by muse, mutect2
- RSC1A1 | c.676G>A p.D226N | Missense Mutation (SNP) | VAF 26/292 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.146); catalogued as rs370483687; called by muse, mutect2
- RYR3 | c.10063C>T p.R3355W (on ENST00000389232; = p.R3356W on NM_001036.6) | Missense Mutation (SNP) | VAF 58/248 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs755340876, COSV66805329; called by muse, mutect2, varscan2
- SLC36A3 | c.1087G>C p.E363Q | Missense Mutation (SNP) | VAF 32/344 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.223); catalogued as COSV100077989, COSV58856720; called by muse, mutect2
- SYT15 | c.785G>A p.R262H | Missense Mutation (SNP) | VAF 23/131 reads (18%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as rs538202309, COSV100970162, COSV99056178; called by muse, mutect2, varscan2
- TPO | c.170C>T p.T57M | Missense Mutation (SNP) | VAF 33/224 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as rs775202863, COSV61097383; called by muse, mutect2, varscan2
- TRPV6 | c.577C>T p.R193C | Missense Mutation (SNP) | VAF 85/377 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs148239732; called by muse, mutect2, varscan2
- TSPOAP1 | c.2146G>C p.E716Q | Missense Mutation (SNP) | VAF 24/252 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1163506922, COSV99269806; called by muse, mutect2
- WNT7A | c.712G>A p.V238M | Missense Mutation (SNP) | VAF 46/490 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV99540776; called by muse, mutect2
- ZNF628 | c.536G>C p.G179A | Missense Mutation (SNP) | VAF 24/141 reads (17%) | SIFT tolerated (0.43); PolyPhen benign (0.009); catalogued as COSV99219728; called by muse, mutect2, varscan2
- ZNF804A | c.2788G>C p.D930H | Missense Mutation (SNP) | VAF 38/516 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.215); catalogued as COSV100166011; called by muse, mutect2
- ATR | c.852T>C p.D284= | Silent (SNP) | VAF 56/770 reads (7%) | catalogued as COSV100637592; called by muse, mutect2
- ECI2 | c.837G>A p.P279= (on ENST00000380118 / NM_206836.3; = p.P249= on NM_006117.2) | Silent (SNP) | VAF 32/324 reads (10%) | catalogued as rs114924821; called by muse, mutect2
- LRP2 | c.5841C>T p.N1947= | Silent (SNP) | VAF 62/300 reads (21%) | catalogued as rs569277988, COSV99786193; called by muse, mutect2, varscan2
- SASH3 | c.907C>A p.R303= | Silent (SNP) | VAF 97/497 reads (20%) | catalogued as rs142835579, COSV63556548; called by muse, mutect2, varscan2
- SCN5A | c.4827G>A p.S1609= (on ENST00000333535 / NM_198056.3; = p.S1608= on NM_000335.5) | Silent (SNP) | VAF 72/451 reads (16%) | catalogued as rs886058460, COSV61126455; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC30A7 | c.612T>C p.H204= | Silent (SNP) | VAF 79/297 reads (27%) | catalogued as COSV100725350; called by muse, mutect2, varscan2
- STRN3 | c.882C>T p.D294= | Silent (SNP) | VAF 109/435 reads (25%) | catalogued as rs746431353, COSV100670204, COSV62580790; called by muse, mutect2, varscan2
- TSSK1B | c.297C>T p.L99= | Silent (SNP) | VAF 9/249 reads (4%) | catalogued as rs888565087, COSV101180922; called by muse, mutect2
- ZNF71 | c.789G>A p.T263= | Silent (SNP) | VAF 32/457 reads (7%) | catalogued as rs201252925, COSV100045500; called by muse, mutect2
- EVL | c.352+12001C>T | Intron (SNP) | VAF 20/84 reads (24%) | catalogued as COSV100762586; called by muse, mutect2, varscan2
- RPL26P30 | n.589C>T | RNA (SNP) | VAF 85/753 reads (11%) | catalogued as rs532812324; called by muse, mutect2, varscan2
